Somatic mutation profile of tumor specimen TCGA-J4-A6G3-01A (aliquot TCGA-J4-A6G3-01A-11D-A30X-08) from TCGA case TCGA-J4-A6G3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.0 years (20,836 days).
Specimen TCGA-J4-A6G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a75c3d7-d9a3-4807-933d-ca76a23d2507.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A6G3-10A (Blood Derived Normal), aliquot TCGA-J4-A6G3-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b4c1e82-4a2e-498c-9089-8fb59e9a5c80

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 14/143 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- CCDC87 | c.1497G>A p.M499I | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV59579202; called by muse, mutect2, varscan2
- GRIP1 | c.2020G>A p.V674M (on ENST00000359742 / NM_001379345.1; = p.V622M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs746921797, COSV54025464; called by mutect2, varscan2
- IQCG | c.470A>T p.Q157L | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV54562458; called by muse, mutect2
- MBNL2 | c.1076A>G p.Y359C (on ENST00000376673 / NM_001382666.1; = p.Y347C on NM_207304.3 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59121264; called by muse, mutect2
- NPC2 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53143495; called by muse, mutect2
- PAG1 | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV55058117; called by muse, mutect2
- PAX9 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV64061667; called by muse, mutect2
- PFKFB4 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 18/113 reads (16%) | PolyPhen probably damaging (0.988); catalogued as COSV99219852; called by muse, varscan2
- PLCB1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV62052817; called by muse, mutect2, varscan2
- SMARCA1 | c.3030+1G>A p.X1010_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | catalogued as COSV64412104; called by muse, mutect2, varscan2
- SSX2IP | c.856A>G p.K286E | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV60552951; called by muse, mutect2
- CDKL4 | c.277del p.R93Efs*10 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel
- CFL1 | c.213del p.F71Lfs*45 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- THRAP3 | c.112_115del p.S38Vfs*7 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- CYB561A3 | c.645C>T p.L215= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV53652062; called by muse, mutect2, varscan2
- FGA | c.309T>C p.H103= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV57396517; called by muse, mutect2
- RAB37 | c.153C>T p.D51= | Silent (SNP) | VAF 20/255 reads (8%) | catalogued as rs530556816, COSV61194837; called by muse, mutect2
- SAMD9 | c.1404A>G p.V468= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs767256482, COSV66075611; called by muse, mutect2, varscan2
- SHROOM1 | c.2358G>A p.L786= (on ENST00000378679 / NM_001172700.2; = p.L781= on NM_133456.2) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60581402; called by muse, mutect2
